Gene-level copy-number profile of tumor specimen TCGA-49-AAR2-01A from TCGA case TCGA-49-AAR2, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.3 years (23,479 days).
Specimen TCGA-49-AAR2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.63ea056f-0145-48eb-8c8a-2409941139c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AAR2-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cd60330-d84b-4bb6-b6d6-06265d61478c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 13,488; copy number 2: 42,954; copy number 3: 2,902; copy number 4: 465; copy number 5: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AAR2-01A-11D-A396-01): tumor purity 0.69, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,546,973–112,642,483, 2 genes: AC137549.1, LINC02200.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,030,284–91,513,775, 6 genes, copy number 5: U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr10:1,989,076–2,081,097, 3 genes, copy number 5 (within-gene range 3–5): LINC00700, AL441943.1, MIR6072.

Autosomal genes at a single copy (total copy number 1): 11,067. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
